Somatic mutation profile of tumor specimen TARGET-10-PARFJK-09A (aliquot TARGET-10-PARFJK-09A-01D) from TARGET case TARGET-10-PARFJK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,249 days).
Specimen TARGET-10-PARFJK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22d50a44-5935-4af9-80af-aaec1c1d3bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFJK-10A (Blood Derived Normal), aliquot TARGET-10-PARFJK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/298f4fec-8985-446d-ba6c-6f7a7159c2a2

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs397507501, CM021125, COSV61008667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP24A1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141152573; called by muse, mutect2, varscan2
- GOLGA1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as rs200680381; called by muse, mutect2, varscan2
- ITGAE | c.2130C>A p.S710R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1454835723; called by muse, mutect2, varscan2
- PSMD1 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433485; called by muse, mutect2, varscan2
- SLC17A2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV55354266; called by muse, mutect2, varscan2
- SLC35F4 | c.707G>A p.R236Q (on ENST00000339762 / NM_001352015.2; = p.R200Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as rs373752532; called by muse, mutect2, varscan2
- SPATA16 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.314); catalogued as rs544088248, COSV63529036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNM | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs373435565; called by muse, mutect2, varscan2
- SOD3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
